Surgical pathology report (de-identified scan), TCGA case TCGA-CF-A1HS, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site ILSBio, specimen TCGA-CF-A1HS-01A (Primary Tumor).

[page 1 of 6]
Form Revised

Clinical Case Report

ICD-0-3

Carcinoma, Squamous cell, NOS
(aka - epidermoid, NOS) 8070/3

Site: bladder, NOS C67.9

lw
2/27/12

Informed Consent

Pathology Discrepancy		

I personally informed this patient that a specimen(s) would be collected to be used for research purposes. I reviewed the **RESEARCH SUBJECT INFORMATION AND CONSENT FORM** with the patient and answered any questions the patient had. The patient then signed the consent form as a free and voluntary act. A copy of this informed consent document will be retained at our institution.

Name of Physician or Study Coordinator

Signature

Date

Clinical Information

GENERAL INFORMATION				
Date of Birth (mm/dd/yyyy)	Height	Marital Status	Race	Temperature
Gender	Weight		Blood Pressure	Heart Rate
☐ Male ☒ Female	52 kg		14/8	

HISTORY OF PRESENT ILLNESS
Chief Complaints: Abdominal pain; fever; blood in the urine
Symptoms: Hematuria; weight loss
Clinical Findings:
Performance Scale (Karnofsky Score): ☐ 100 Asymptomatic ☐ 80-90 Symptomatic but Fully Ambulatory ☐ 60-70 Symptomatic, in bed less than 50% of day ☒ 40-50 Symptomatic, in bed more than 50% of day, but not bed ridden ☐ 20-30 Bed Ridden

CURRENT MEDICATIONS				
Drug	Dose	Route	Frequency	Date (mm/dd/yyyy)
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /

[page 2 of 6]
PAST MEDICAL HISTORY			
Diagnosis/Disease/Disorder/Injury	Diagnosis Date	Treatment	Status

OB/GYN HISTORY			
Menopausal Status ☐ Pre-menopausal ☐ Peri-Menopausal ☒ Post-menopausal	Date of First Menses	# of Pregnancies	
	Date of Last Menses years old	# of Live Births	
Birth Control: ☐ Condom ☐ Oral Contraceptive ☒ IUD ☐ Other:			☐ Hormone Replacement Therapy:

SOCIAL HISTORY				
Occupation:		Environmental Hazards:		
Smoking History				
Current Status	TYPE	Packs/day	Duration	When Quit
☐ YES ☒ NO			(yrs)	(yr)
Alcohol Consumption				
Current Status	TYPE	Drinks/day	Duration	When Quit
☐ YES ☒ NO			(yrs)	(yr)
Drug Use				
Current Status	TYPE	Frequency	Duration	When Quit
☐ YES ☒ NO			(yrs)	(yr)

FAMILY MEDICAL HISTORY		
Relative	Diagnosis	Age of Diagnosis

LAB DATA						
Test	Result	Date	Test	Result	Date	
HIV	☒ Negative ☐ Positive:		CEA	☐ Negative ☐ Positive:		
Hep B	☒ Negative ☐ Positive:		CA 15-3	☐ Negative ☐ Positive:		
Hep C	☒ Negative ☐ Positive:		CA 19-9	☐ Negative ☐ Positive:		
AFP	☐ Negative ☐ Positive:		PSA	☐ Negative ☐ Positive:		
Other:	☐ Negative ☐ Positive:		Other:	☐ Negative ☐ Positive:		
B/T Cell Markers:						

[page 3 of 6]
DIAGNOSTIC STUDIES		
Study	Results	Date
Ultrasound	A tumour in the U. bladder.	
X-Ray		
CT		
Endoscopy		
MRI		
Biopsy		

CLINICAL DIAGNOSIS		
Preoperative Clinical Diagnosis		
Location of Suspected Involved Lymph Nodes	Location of Suspected Distant Metastasis	
Clinical Staging		Date of Diagnosis
T ₃ N ₀ M ₀ Stage: III		

Treatment Information

SURGICAL TREATMENT			
Procedure		Date of Procedure	
U. Bladder Resection			
Primary Tumor			
Organ	Detailed Location	Size	
Urinary bladder tumor		5 x 4 x 2 cm	
Extension of Tumor			
Lymph Nodes			
Description	Location of Lymph Nodes	# of Lymph Nodes	
Palpable, Non-Dissected Lymph Nodes			
Dissected Lymph Nodes			
Distant Metastasis			
Organ	Detailed Location	Size	
Surgical Staging			
T ₃ N ₀ M ₀ Stage: III			

NEOADJUVANT THERAPY (Chemo, Radiation, Immuno, Hormonal, or Molecular)				
Drug/Treatment	Dose	Route	Frequency	Date (mm/dd/yyyy)
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /

[page 4 of 6]
Pathology Form

Specimen Information

Collected by: _____ Date: _____ Time: _____

Preserved by: _____ Date: _____

SPECIMEN TYPE (# of samples provided)							
Frozen		Paraffin Block		Blood/Serum/Plasma		Slide	
Diseased	Normal	Diseased	Normal	Diseased	Normal	Diseased	Normal
4	2	4	2			4	2
Time to LN2		Time to Formalin		Time to LN2			
11 min		12 min					

PATHOLOGICAL DESCRIPTION			
Primary Tumor			
Organ	Size	Extension of Tumor	Distance to NAT
urinary bladder tumor	5 x 4 x 2 cm		5 cm
Lymph Nodes			
Location	# Examined	# Metastasized	
Distant Metastasis			
Organ	Detailed Location	Size	
Pathological Staging			
pT 3 N0 M0		Stage: III	
Notes:			

[page 5 of 6]
Microscopic Description

Histological Pattern											
Cell Distribution			+	-	Structural Pattern			+	-		
Diffuse					Streaming						
Mosaic					Storiform						
Necrosis					Fibrosis						
Lymphocytic Infiltration					Palisading						
Vascular Invasion					Cystic Degeneration						
Clusterized					Bleeding						
Alveolar Formation					Myxoid Change						
Indian File					Psammoma/Calcification						

Cellular Differentiation																			
Squamous			+	-	Adenomatous			+	-	Sarcomatous			+	-	Lymphomatous			+	-
Squamoid Cell	✓				Glandular cell					Round Cell					Large Cell				
Spindle Cell					Cell Stratification					Fibroblast					Small Cell				
Keratin	✓				Secretion					Osteoblast					RS Cell/RS Like				
Desmosome					Intracyt. Vacuole					Lipoblast					Inflam. Cell				
Pearl					Gland formation					Myoblast					Plasma Cell				

Cellular Differentiation:	Well ☒	Moderate	Poor
---------------------------	--	----------	------

Nuclear Appearance				
Nuclear Atypia:	0	I	II	III
Aniso Nucleosis		✓		
Hyperchromatism			✓	
Nucleolar Prominent			✓	
Multinucleated Giant Cell			✓	
Mitotic Activity			✓	

Nuclear Grade:			
----------------	--	--	--

IHC Data			
Marker	Result	Value	Date
ER	☐ Negative ☐ Positive		
PR	☐ Negative ☐ Positive		
Her-2/neu	☐ Negative ☐ Positive		
B-Cell Marker	☐ Negative ☐ Positive		
T-Cell Marker	☐ Negative ☐ Positive		
Other:	☐ Negative ☐ Positive		
Other:	☐ Negative ☐ Positive		

Final Pathology Report

8070/3

Histological Diagnosis: Epidermoid carcinoma of the bladder Grade: I

Comments:

Principal Investigator

Pathologist

Date

[page 6 of 6]
CONSOLIDATED DIAGNOSTIC PATHOLOGY FORM*

Microscopic Appearance:

1. Histological pattern:

CELL DISTRIBUTION		STRUCTURAL PATTERN	
Diffuse	☒	Streaming	☒
Mosaic	☒	Storiform	☐
Necrosis	☒	Fibrosis	☐
Lymphocytic Infiltration	☒	Palisading	☐
Vascular Invasion	☐	Cystic Degeneration	☐
Clusterized	☒	Bleeding	☐
Alveolar Formation	☐	Myxoid Change	☐
Indian File	☐	Psammoma/Calcification	☐

2. Cellular features:

Squamous	+	-	Adenomatous	+	-	Sarcomatous	+	-	Lymphomatous	+	-
Squamoid Cell	☒	☐	Glandular cell	☐	☐	Round Cell	☐	☐	Large Cell	☐	☐
Spindle Cell	☒	☐	Cell Stratification	☐	☐	Fibroblast	☐	☐	Small Cell	☐	☐
Keratin	☒	☐	Secretion	☐	☐	Osteoblast	☐	☐	RS Cell/RS Like	☐	☐
Desmosome	☒	☐	Intracyt. Vacuole	☐	☐	Lipoblast	☐	☐	Inflam. Cell	☐	☐
Pearl	☒	☐	Gland formation	☐	☐	Myoblast	☐	☐	Plasma Cell	☐	☐
Otherwise Specified: D1 75% D2 75% D3 75% D4 75%											

2. Cellular Differentiation:

Well	Moderately	Poor
☐	☐	☒

Necrosis 5%

3. Nuclear Atypia:

Nuclear Appearance	0	I	II	III
Aniso Nucleosis	☐	☐	☐	☒
Hyperchromatism	☐	☐	☐	☒
Nucleolar Prominent	☐	☐	☐	☒
Multinucleated Giant Cell	☐	☐	☐	☒
Mitotic Activity	☐	☐	☐	☒
Nuclear Grade	☐	☐	☐	☒

8074/3

Histological Diagnosis: Squamous Cell Carcinoma, G2

Comments: _____

Date _____

Director, Research Pathology

*(INTEGRATED REPORT OF FINDINGS BY CONTRIBUTOR AND

PATHOLOGIST STAFF FOR RESEARCH USE ONLY).

Source: NCI Genomic Data Commons file 086daaa0-403e-4cfd-9daa-34d8019a7273 (TCGA-CF-A1HS.48DB8720-833D-467C-8BF2-95EF539B4D5E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).